Surgical pathology report (de-identified scan), TCGA case TCGA-24-2288, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2288-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT
FINAL

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN :

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

TCGA - 24 - 2288

DIAGNOSIS:

OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS CARCINOMA POORLY DIFFERENTIATED, INVOLVING OVARY AND FALLOPIAN TUBE

OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY
- PAPILLARY SEROUS CARCINOMA, POORLY DIFFERENTIATED INVOLVING OVARY AND FALLOPIAN TUBE WITH EXTENSIVE LYMPHOVASCULAR SPACE INVASION

OMENTUM, OMENTECTOMY (FS)
- METASTATIC CARCINOMA

OMENTUM, OMENTECTOMY
- METASTATIC CARCINOMA

SMALL INTESTINE, RESECTION
- METASTATIC CARCINOMA, MULTIPLE NODULES INVOLVING MESENTERY AND SMALL INTESTINE WALL
- METASTATIC CARCINOMA PRESENT IN 5 OF 5 MESENTERIC LYMPH NODES (5/5)

SOFT TISSUE, VENTRAL HERNIA, HERNIORRHAPHY
- METASTATIC CARCINOMA, SOFT TISSUE AND DERMAL INVOLVEMENT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Diagnosis Comment

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS
1. A neoplasm is PRESENT

2. The HISTOLOGIC DIAGNOSIS is:

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Serous adenocarcinoma

3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of >50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube (bilaterally)
9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 8.0 cm
14. Metastatic involvement of the uterine serosa CANNOT BE EVALUATED.
15. Metastatic involvement of the endometrium CANNOT BE EVALUATED.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring > 2 cm in greatest dimension

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

18. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to O.R. to pickup 'omentum.' It consists of a 7 x 3 x 2.0 cm glistening fleshy white mass. A representative section is submitted for FS1. An additional portion is submitted for tumor bank. The remainder is placed in formalin."

[page 3 of 4]
[REDACTED]

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis. [REDACTED]

History:

The patient is a [REDACTED] with enlarged uterus and ovarian and omental masses. A previous cervical biopsy showed poorly differentiated carcinoma (S99-10--). Operative Procedure: Exploratory laparotomy; omentectomy; bilateral salpingo-oophorectomy; ventral hernia repair; small bowel resection.

Specimen(s) Received:

A: OMENTUM (FOR FS)
B: OMENTUM, ROUTINE
C: SMALL BOWEL
D: LEFT OVARY
E: RIGHT OVARY AND TUBE
F: HERNIA SAC

Gross Description:

The specimens are received in six formalin-filled containers labeled with the patient's name. In addition, the first container is labeled "omentum (FS1)." It holds a previously sectioned white, firm, well-demarcated mass measuring 7 x 5 x 2.5 cm, in aggregate, and a cassette labeled "FS" holding a section of tumor measuring 3 x 1.5 x 0.2 cm. On multiple sections, the tumor shows solid, focally necrotic, homogeneous cut surfaces. Labeled A1 - FS; A2 and A3 - additional sections of tumor. [REDACTED]

The second container is labeled "omentum." It contains fragments of fatty tissue with attached vessels, consistent with omentum, measuring 10 x 5 x 3 cm. Multiple white, firm nodules, ranging in size from 0.2 to 3 cm, are scattered on the omental surface. All these nodules show firm, white, solid and partially cystic and hemorrhagic cut surfaces. Labeled B1 - sections of two different nodules. [REDACTED]

The third container is labeled "small bowel." It contains several adhered loops of small intestine centered around a large solid white, fleshy omental mass. The length of the small intestine is difficult to appreciate due to the degree of distortion; it is ~100 cm in length. The lumen is even and ~2.5 cm in diameter. In the area encroached by tumor, the lumen of the intestine appears narrowed to a diameter of 1 cm. However, the intestine is lined by unremarkable mucosa throughout its length, with no evidence of intraluminal tumor. The tumor surrounds the intestinal loop, involves the mesentery with multiple additional white nodules, ranging in size from 0.5 to 3 cm, studding the peritoneal surface. Tumor nodules are also present at the stapled mesenteric resection margin. The main tumor measures 10 cm in greatest dimension. Labeled C1 and C2 - intestine with serosal tumor; C3 - stapled resection margins of the intestine; C4 - mesenteric lymph nodes/tumor nodules [REDACTED]

The fourth container is labeled "left ovary." It contains a 7.5 x 5 x 4 cm solid ovoid firm white mass with irregular surface. A portion of the surface is represented by a thin-walled white cyst. The mass is bisected to show solid white, soft cut surfaces with areas of necrosis. The above described cyst contains necrotic, yellow fluid. There is no recognizable residual ovarian tissue. Also, no fallopian tube is identified grossly. Labeled D1 to D3 - sections of the tumor (including cyst). [REDACTED]

The fifth container is labeled "right ovary." It holds an ovary with attached fallopian tube. The ovary is 4 x 3 x 2 cm and the fallopian tube is 5 cm in length and 0.5 cm in average diameter, and includes the proximal third of the fallopian tube as well as the fimbriated end. The ovary appears to be entirely replaced by a multinodular firm solid white tumor. In addition, multiple tumor nodules ranging in size from 0.2 to 1 cm are present on the tubo-ovarian ligament and serosa overlying the fallopian tube, including the fimbriated end of the tube. Labeled E1 - ovarian tumor (including tubo-ovarian ligament); E2 - fallopian tube (transverse sections and fimbriated end). [REDACTED]

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

The sixth container is labeled "hernia sac, skin, tumor." It holds a sac-like portion of skin with attached serosa measuring 21 x 6 x 5 cm. A portion of this sac shows a ring-like structure consistent with markedly distended umbilical scar. The serosal surface of the hernia sac shows extensive serosal thickening on a plaque-like area of 8 x 4 cm, as well as an additional 8 x 7 x 4 cm nodule of firm solid tumor, involving the serosa and fat adjacent to the above described putative umbilical scar. In addition, multiple small firm tumor nodules are scattered on the serosal surface. The skin is tan, wrinkled and shows extensive areas of hyperkeratosis. No tumors are seen on the skin surface. Cross sections of the largest nodule and of the sac show multiple tumor nodules infiltrating through the serosa into the dermis. Also, the largest tumor nodule shows solid, extensively necrotic cut surfaces with areas of cystic and hemorrhagic degeneration. The tumor is present in the subcutaneous fat underlying the skin of the hernia sac. Labeled F1 and F2. Jar 2.

Source: NCI Genomic Data Commons file 718e610f-0d0a-405b-ba4c-e8f3e783de9e (TCGA-24-2288.A8D48A3E-3F22-44EC-8CBD-2AD8BB43BB45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).